Somatic mutation profile of tumor specimen 0DRGF1 from CCDI case PBCFMA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Brain stem; Age at diagnosis: 0.8 years (293 days).
Specimen 0DRGF1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3f79820-f27a-4603-9f19-e8959d6ff58a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRGEG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8bb88c2-5d39-4653-bc73-751e0812e626

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PGBD5 | c.442G>A p.V148I (on ENST00000525115; = p.V217I on NM_001258311.2) | Missense Mutation (SNP) | VAF 227/494 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs566300521; called by muse, mutect2, varscan2
- ESM1 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 38/1406 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2
- EOLA1 | c.204T>A p.I68= | Silent (SNP) | VAF 23/802 reads (3%) | called by muse, mutect2
- ATG13 | c.789+88C>T | Intron (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
